Somatic mutation profile of tumor specimen TCGA-GS-A9TY-01A (aliquot TCGA-GS-A9TY-01A-11D-A38X-10) from TCGA case TCGA-GS-A9TY, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Lymph nodes of axilla or arm; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-GS-A9TY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fccf2757-84d7-4d68-977e-2dc7cf31da95.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GS-A9TY-10A (Blood Derived Normal), aliquot TCGA-GS-A9TY-10A-01D-A38X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/105d28a5-5b2c-4b93-b236-16315c6a0e33

The open-access MAF lists 156 somatic variants for this specimen: 119 protein-altering or splice-affecting, 34 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 103, Silent 34, Frame Shift Del 8, Nonsense Mutation 4, 3'Flank 2, Splice Site 1, Frame Shift Ins 1, Translation Start Site 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- B2M | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 53/63 reads (84%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as rs1023835002, COSV62562840, COSV62562870, COSV62563658; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- IRF8 | c.238A>G p.T80A | Missense Mutation (SNP) | VAF 58/93 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs397514711, CM116643, COSV51897805; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.695T>C p.I232T | Missense Mutation (SNP) | VAF 33/39 reads (85%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs587781589, CM103212, COSV52661257, COSV52760307, COSV52829354; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AASS | c.1446G>C p.K482N | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs549330560, COSV100741888; called by muse, mutect2, varscan2
- ABCB5 | c.2793T>A p.F931L (on ENST00000404938 / NM_001163941.2; = p.F486L on NM_178559.6) | Missense Mutation (SNP) | VAF 65/172 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.207); catalogued as COSV99329731; called by muse, mutect2, varscan2
- ADAMTS20 | c.1771G>A p.G591R | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs375621283, COSV67136889; called by muse, mutect2, varscan2
- ADCY2 | c.1856T>C p.I619T | Missense Mutation (SNP) | VAF 81/230 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as COSV100604191; called by muse, mutect2, varscan2
- AKAP4 | c.199G>A p.G67S | Missense Mutation (SNP) | VAF 100/263 reads (38%) | SIFT tolerated (0.51); PolyPhen benign (0.006); catalogued as COSV100654372, COSV62075579; called by muse, mutect2, varscan2
- ANKFY1 | c.3455C>T p.P1152L (on ENST00000341657 / NM_001330063.2; = p.P1153L on NM_016376.5) | Missense Mutation (SNP) | VAF 26/35 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100493182; called by muse, mutect2, varscan2
- ANO5 | c.607G>T p.D203Y | Missense Mutation (SNP) | VAF 46/81 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV100202248; called by muse, mutect2, varscan2
- BRCA1 | c.4301G>A p.S1434N | Missense Mutation (SNP) | VAF 64/107 reads (60%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV58793891; called by muse, mutect2, varscan2
- BTG2 | c.136C>G p.L46V | Missense Mutation (SNP) | VAF 49/77 reads (64%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); catalogued as COSV99306027; called by muse, mutect2, varscan2
- CARD11 | c.559C>T p.R187W | Missense Mutation (SNP) | VAF 100/241 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.019); catalogued as COSV62717095; called by muse, mutect2, varscan2
- CD320 | c.244G>C p.D82H | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs944102596, COSV100035903; called by muse, mutect2, varscan2
- CDH26 | c.484G>T p.A162S | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV99722999; called by muse, mutect2, varscan2
- CFAP47 | c.973A>T p.I325F | Missense Mutation (SNP) | VAF 295/741 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as rs1173398550, COSV99935869; called by muse, mutect2, varscan2
- CHD3 | c.1460T>C p.L487P | Missense Mutation (SNP) | VAF 34/47 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100391722; called by muse, mutect2, varscan2
- CHD5 | c.1369T>A p.C457S | Missense Mutation (SNP) | VAF 46/72 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV99315106; called by muse, varscan2
- CHD5 | c.1324T>G p.C442G | Missense Mutation (SNP) | VAF 52/87 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99315109; called by muse, varscan2
- COL5A3 | c.1793C>T p.P598L | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.894); catalogued as rs147814824; called by muse, mutect2, varscan2
- CPS1 | c.2570C>A p.A857D | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV99244110; called by muse, mutect2, varscan2
- CST3 | c.17G>A p.R6H | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV100976895; called by muse, mutect2, varscan2
- DACH2 | c.884G>T p.G295V | Missense Mutation (SNP) | VAF 144/647 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV64172901; called by muse, mutect2, varscan2
- DCAF8 | c.1748C>T p.S583L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs867856057, COSV100470864; called by muse, mutect2, varscan2
- DDX60 | c.982G>C p.A328P | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101190674, COSV67099333; called by muse, mutect2, varscan2
- DENND5B | c.2876T>A p.I959N | Missense Mutation (SNP) | VAF 119/250 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100172240; called by muse, mutect2, varscan2
- DGAT2L6 | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 44/201 reads (22%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.477); catalogued as rs1289127200, COSV60717354; called by muse, mutect2, varscan2
- DRG2 | c.438G>A p.M146I | Missense Mutation (SNP) | VAF 50/64 reads (78%) | SIFT tolerated (0.1); PolyPhen benign (0.056); catalogued as COSV99855069; called by muse, mutect2, varscan2
- EXOC7 | c.533A>T p.D178V | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as COSV100135790, COSV58741169; called by muse, mutect2, varscan2
- FLRT1 | c.923C>T p.T308M | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.781); catalogued as rs750867527, COSV99736239; called by muse, mutect2, varscan2
- FRMPD1 | c.4381C>T p.R1461C | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs199593687, COSV100899637; called by muse, mutect2, varscan2
- GLS | c.223T>G p.S75A | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.006); catalogued as COSV100290549; called by muse, mutect2, varscan2
- GPRASP1 | c.2873A>T p.E958V | Missense Mutation (SNP) | VAF 75/193 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1382344067, COSV100851082; called by muse, mutect2, varscan2
- GRM1 | c.2795C>G p.P932R | Missense Mutation (SNP) | VAF 33/36 reads (92%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.855); catalogued as COSV99269085; called by muse, mutect2, varscan2
- HARBI1 | c.608T>C p.L203P | Missense Mutation (SNP) | VAF 69/116 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV100366044; called by muse, mutect2, varscan2
- HOXC9 | c.719T>A p.F240Y | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100327642; called by muse, mutect2, varscan2
- HS3ST1 | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.51); PolyPhen benign (0.384); catalogued as rs762454446, COSV99137017; called by muse, mutect2, varscan2
- IDH3A | c.293C>T p.P98L | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100211051; called by muse, varscan2
- IFT172 | c.2983G>A p.V995M | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.575); catalogued as COSV99563370; called by muse, mutect2, varscan2
- IGHG2 | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 48/96 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs1439659583; called by muse, mutect2, varscan2
- IGHV2-70 | c.137T>A p.F46Y | Missense Mutation (SNP) | VAF 99/119 reads (83%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.922); catalogued as rs554824536; called by muse, varscan2
- IGLV3-1 | c.58T>C p.S20P | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT deleterious (0.01); PolyPhen benign (0.312); catalogued as rs761874852; called by muse, varscan2
- IGLV3-1 | c.335G>C p.S112T | Missense Mutation (SNP) | VAF 18/23 reads (78%) | SIFT tolerated (0.09); PolyPhen benign (0.216); catalogued as rs374018767; called by muse, mutect2, varscan2
- IL6 | c.175T>C p.Y59H | Missense Mutation (SNP) | VAF 76/126 reads (60%) | SIFT tolerated (0.17); PolyPhen benign (0.029); catalogued as rs201822486, COSV99331631; called by muse, varscan2
- IL6 | c.187G>A p.G63S | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.367); catalogued as rs752257060, COSV99331427, COSV99331635; called by muse, varscan2
- INHA | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 49/201 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as rs754976939, COSV99217530; called by muse, mutect2, varscan2
- KCNJ8 | c.1081A>C p.K361Q | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.836); catalogued as COSV99557728; called by muse, mutect2
- KMT2D | c.11164C>T p.Q3722* | Nonsense Mutation (SNP) | VAF 25/36 reads (69%) | catalogued as COSV99985916; called by muse, mutect2, varscan2
- LAMB1 | c.1765G>A p.V589I | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV99741721; called by muse, mutect2, varscan2
- MARCO | c.959C>A p.A320D | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.521); catalogued as rs1274097052, COSV59057221; called by muse, mutect2, varscan2
- MAST4 | c.680G>A p.R227Q (on ENST00000403625 / NM_001164664.2; = p.R38Q on NM_015183.3) | Missense Mutation (SNP) | VAF 113/135 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1226140923, COSV55123907; called by muse, mutect2, varscan2
- MBD3L1 | c.491_494del p.V164Efs*6 | Frame Shift Del (DEL) | VAF 22/64 reads (34%) | catalogued as rs758076001; called by mutect2, pindel, varscan2
- MED22 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 83/139 reads (60%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.642); catalogued as COSV59298472; called by muse, mutect2, varscan2
- MEGF8 | c.4150C>T p.L1384F (on ENST00000251268 / NM_001271938.2; = p.L1317F on NM_001410.3) | Missense Mutation (SNP) | VAF 52/63 reads (83%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as COSV99239142; called by muse, mutect2, varscan2
- MGAM | c.5559G>T p.W1853C | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV101527765; called by muse, mutect2, varscan2
- MICAL1 | c.2018C>A p.P673Q | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.786); catalogued as COSV99238181; called by muse, mutect2, varscan2
- MSL2 | c.359T>C p.I120T | Missense Mutation (SNP) | VAF 60/142 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV99388239; called by muse, mutect2, varscan2
- MSLN | c.1273C>T p.R425C (on ENST00000382862 / NM_013404.4; = p.R417C on NM_005823.6) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as rs186022569, COSV99558778; called by mutect2, varscan2
- MUC17 | c.13049C>A p.S4350Y | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV100073384, COSV60280672; called by muse, mutect2, varscan2
- MYL6B | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 58/141 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as rs950965377, COSV99255152; called by muse, mutect2, varscan2
- MYO18B | c.4581G>A p.M1527I | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.269); catalogued as COSV59148336; called by muse, varscan2
- NGEF | c.941C>T p.A314V | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.024); catalogued as rs183477550, COSV50939247; called by muse, mutect2
- NHS | c.4438G>A p.G1480S | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV101197008; called by muse, mutect2, varscan2
- OR10A4 | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as rs146085036; called by muse, mutect2, varscan2
- OR14I1 | c.466G>A p.V156I | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.042); catalogued as rs761639634, COSV61200667; called by muse, mutect2, varscan2
- PARP12 | c.1373G>A p.R458H | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1230260195, COSV99694221, COSV99694287; called by muse, mutect2, varscan2
- PBRM1 | c.161A>G p.Y54C | Missense Mutation (SNP) | VAF 51/86 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56274956; called by muse, mutect2, varscan2
- PCDH11X | c.827C>T p.A276V | Missense Mutation (SNP) | VAF 36/240 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV100012835; called by muse, mutect2, varscan2
- PCDHA12 | c.1448A>C p.D483A | Missense Mutation (SNP) | VAF 81/175 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100254621; called by muse, mutect2, varscan2
- PCSK5 | c.2154C>G p.N718K | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.223); catalogued as COSV100950713; called by muse, mutect2, varscan2
- PEX19 | c.401G>A p.S134N | Missense Mutation (SNP) | VAF 54/274 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV100926990; called by muse, mutect2, varscan2
- PHOX2B | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.027); catalogued as COSV99891726; called by muse, mutect2, varscan2
- PIK3CG | c.2683A>G p.T895A | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.81); PolyPhen benign (0.029); catalogued as COSV63250442; called by muse, mutect2, varscan2
- QARS1 | c.1891G>T p.A631S | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.071); catalogued as COSV100070286; called by muse, mutect2, varscan2
- RAPH1 | c.3370C>T p.R1124* | Nonsense Mutation (SNP) | VAF 107/250 reads (43%) | catalogued as rs1383820931, COSV99864538; called by muse, mutect2, varscan2
- RGS14 | c.772C>T p.R258* | Nonsense Mutation (SNP) | VAF 10/59 reads (17%) | catalogued as COSV101281753; called by muse, mutect2, varscan2
- RTN2 | c.1406C>A p.T469N | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs190900651; called by muse, mutect2, varscan2
- RUNX1T1 | c.298G>A p.G100R (on ENST00000265814 / NM_001198628.1; = p.G73R on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56167304, COSV99755048; called by muse, mutect2, varscan2
- SCNN1G | c.328G>A p.V110I | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as rs147276737; called by mutect2, varscan2
- SEMA3C | c.1933G>T p.A645S | Missense Mutation (SNP) | VAF 57/134 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.393); catalogued as COSV99543935; called by muse, mutect2, varscan2
- SEMA6D | c.2039G>C p.G680A (on ENST00000316364 / NM_153618.2; = p.G618A on NM_020858.2) | Missense Mutation (SNP) | VAF 132/163 reads (81%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV100317661, COSV60382780; called by muse, mutect2, varscan2
- SIX4 | c.1100A>G p.N367S | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99382519; called by muse, mutect2, varscan2
- SLC19A1 | c.533G>A p.G178D | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV100229661; called by muse, mutect2
- SLC27A1 | c.1864G>A p.D622N | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0.079); catalogued as COSV99393654; called by muse, mutect2, varscan2
- SLC2A14 | c.1324T>G p.L442V | Missense Mutation (SNP) | VAF 76/92 reads (83%) | SIFT tolerated (0.05); PolyPhen benign (0.34); catalogued as COSV100534055; called by muse, mutect2, varscan2
- SLC41A1 | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.108); catalogued as rs756582015, COSV100900514; called by muse, mutect2, varscan2
- SLX4 | c.5264C>T p.A1755V | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs372921011; ClinVar: uncertain significance; called by mutect2, varscan2
- SMCR8 | c.1477C>T p.L493F | Missense Mutation (SNP) | VAF 22/27 reads (81%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.896); catalogued as rs113043428, COSV100329324; called by muse, mutect2, varscan2
- SMG5 | c.2783A>G p.K928R | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.025); catalogued as rs892696096, COSV99431646; called by muse, mutect2, varscan2
- SPATA17 | c.426A>T p.K142N | Missense Mutation (SNP) | VAF 32/35 reads (91%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as COSV100861235; called by muse, mutect2, varscan2
- SPIN3 | c.31G>T p.G11W | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as COSV100888499; called by muse, mutect2, varscan2
- STXBP3 | c.959G>A p.G320E | Missense Mutation (SNP) | VAF 12/312 reads (4%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.618); catalogued as COSV100894100; called by muse, mutect2
- TASOR2 | c.5494C>G p.L1832V | Missense Mutation (SNP) | VAF 68/81 reads (84%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as COSV100051095; called by muse, mutect2, varscan2
- TBRG1 | c.640G>A p.V214M | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs369320849; called by muse, mutect2, varscan2
- TENM4 | c.8105C>T p.A2702V | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs775560022, COSV99579467; called by muse, mutect2, varscan2
- TENT4A | c.778A>C p.M260L | Missense Mutation (SNP) | VAF 122/327 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.365); catalogued as COSV100049306; called by muse, mutect2, varscan2
- TJP1 | c.3067G>C p.A1023P | Missense Mutation (SNP) | VAF 109/135 reads (81%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); catalogued as COSV100633191; called by muse, mutect2, varscan2
- TMEM74 | c.719C>T p.T240M | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52464262; called by muse, mutect2, varscan2
- TNS2 | c.3072dup p.D1025Rfs*40 (on ENST00000314250 / NM_170754.4; = p.D1035Rfs*40 on NM_015319.2) | Frame Shift Ins (INS) | VAF 30/68 reads (44%) | catalogued as rs764460526; called by mutect2, varscan2
- TRIM23 | c.944G>A p.R315H | Missense Mutation (SNP) | VAF 80/253 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV51551523; called by muse, mutect2, varscan2
- TRNT1 | c.472A>C p.M158L | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.07); catalogued as rs771781629, CM1411166, COSV99285931; called by muse, mutect2, varscan2
- TSNARE1 | c.1438C>T p.R480W | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs546251254, COSV100211504; called by muse, mutect2, varscan2
- TTLL10 | c.497G>A p.G166E (on ENST00000379289 / NM_001130045.2; = p.G93E on NM_153254.3) | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs1171868105, COSV101016937; called by muse, varscan2
- UBR4 | c.15382C>T p.R5128C | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1246268061, COSV64394667; called by muse, mutect2, varscan2
- XRCC5 | c.465G>C p.K155N | Missense Mutation (SNP) | VAF 97/216 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.906); catalogued as COSV101079919; called by muse, mutect2, varscan2
- XRCC5 | c.1354A>G p.N452D | Missense Mutation (SNP) | VAF 73/94 reads (78%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV101079920; called by muse, mutect2, varscan2
- ZFHX4 | c.2455G>T p.E819* | Nonsense Mutation (SNP) | VAF 35/69 reads (51%) | catalogued as COSV99267953; called by muse, mutect2, varscan2
- ZNF608 | c.401G>A p.G134D | Missense Mutation (SNP) | VAF 110/128 reads (86%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as rs1164117185, COSV100102457; called by muse, mutect2, varscan2
- ALDH5A1 | c.1017_1033del p.C340Ifs*9 | Frame Shift Del (DEL) | VAF 44/118 reads (37%) | called by mutect2, pindel, varscan2
- EXPH5 | c.783del p.K261Nfs*15 | Frame Shift Del (DEL) | VAF 187/410 reads (46%) | called by mutect2, varscan2
- EZR | c.1597-3_1597-2del p.X533_splice | Splice Site (DEL) | VAF 79/107 reads (74%) | called by mutect2, pindel, varscan2
- H2BC11 | c.311_341del p.P104Rfs*16 | Frame Shift Del (DEL) | VAF 17/78 reads (22%) | called by mutect2, pindel, varscan2
- IGLC2 | c.313T>G p.C105G | Missense Mutation (SNP) | VAF 77/204 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); called by muse, varscan2
- IGLV4-69 | c.88G>C p.A30P | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.031); called by muse, varscan2
- IGLV4-69 | c.158_173del p.I53Sfs*10 | Frame Shift Del (DEL) | VAF 30/74 reads (41%) | called by pindel, varscan2
- LUC7L2 | c.912del p.R304Sfs*42 | Frame Shift Del (DEL) | VAF 37/63 reads (59%) | called by mutect2, pindel, varscan2
- PSMB2 | c.139_140del p.V47Wfs*21 | Frame Shift Del (DEL) | VAF 75/197 reads (38%) | called by pindel, varscan2
- ZC3H4 | c.1480_1482del p.K494del | In Frame Del (DEL) | VAF 11/55 reads (20%) | called by mutect2, pindel, varscan2
- ZNF292 | c.6150del p.D2051Tfs*9 | Frame Shift Del (DEL) | VAF 114/144 reads (79%) | called by mutect2, varscan2
- ARHGEF2 | c.1497A>C p.V499= (on ENST00000361247 / NM_001162383.2; = p.V471= on NM_004723.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 25/102 reads (25%) | catalogued as COSV100561185; called by muse, mutect2, varscan2
- CELA1 | c.285C>T p.I95= | Silent (SNP) | VAF 15/90 reads (17%) | catalogued as rs779931346, COSV53330391; called by muse, mutect2, varscan2
- CHST13 | c.903C>T p.R301= | Silent (SNP) | VAF 27/105 reads (26%) | catalogued as COSV100081382; called by muse, mutect2, varscan2
- DIS3L2 | c.810C>T p.P270= | Silent (SNP) | VAF 58/153 reads (38%) | catalogued as COSV99807303; called by muse, mutect2, varscan2
- DST | c.1506C>T p.I502= (on ENST00000361203 / NM_001374722.1; = p.I176= on NM_001723.6) | Silent (SNP) | VAF 142/506 reads (28%) | catalogued as COSV55004379, COSV99760144; called by muse, mutect2, varscan2
- FLRT3 | c.472C>T p.L158= | Silent (SNP) | VAF 38/165 reads (23%) | catalogued as COSV99443876; called by muse, mutect2, varscan2
- FST | c.90G>C p.G30= | Silent (SNP) | VAF 33/119 reads (28%) | catalogued as COSV99887513; called by muse, mutect2, varscan2
- GLUD2 | c.921G>A p.Q307= | Silent (SNP) | VAF 223/388 reads (57%) | catalogued as COSV100047105; called by muse, mutect2, varscan2
- GRPR | c.1020C>T p.C340= | Silent (SNP) | VAF 22/103 reads (21%) | catalogued as COSV100977706; called by muse, mutect2, varscan2
- HOXB5 | c.570C>T p.T190= | Silent (SNP) | VAF 28/58 reads (48%) | catalogued as COSV53314573; called by muse, mutect2, varscan2
- IGHV2-70 | c.138C>T p.F46= | Silent (SNP) | VAF 102/122 reads (84%) | catalogued as rs374979633; called by muse, varscan2
- IGHV3-53 | c.66G>A p.Q22= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as rs781882434; called by muse, mutect2, varscan2
- IGHV3-66 | c.66G>A p.Q22= | Silent (SNP) | VAF 28/165 reads (17%) | catalogued as rs782393884; called by muse, mutect2, varscan2
- MAGEC2 | c.27C>T p.F9= | Silent (SNP) | VAF 42/53 reads (79%) | catalogued as COSV99909748; called by muse, mutect2, varscan2
- MAGT1 | c.450G>A p.R150= (on ENST00000618282 / NM_001367916.1; = p.R182= on NM_032121.5) | Silent (SNP) | VAF 16/137 reads (12%) | catalogued as COSV100800460; called by muse, mutect2, varscan2
- MTREX | c.651T>G p.T217= | Silent (SNP) | VAF 93/190 reads (49%) | catalogued as COSV100044539; called by muse, mutect2, varscan2
- MUC16 | c.36243C>T p.T12081= | Silent (SNP) | VAF 40/93 reads (43%) | catalogued as rs200620444; called by muse, mutect2, varscan2
- NEFH | c.1215C>T p.L405= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as COSV100151848; called by muse, mutect2, varscan2
- PCDH17 | c.1770C>T p.N590= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as rs1186081255, COSV64972705; called by muse, mutect2, varscan2
- PIM1 | c.105G>A p.E35= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as rs762539338, COSV100998780; called by muse, varscan2
- PIM1 | c.432C>T p.A144= | Silent (SNP) | VAF 25/120 reads (21%) | catalogued as COSV100998753; called by muse, mutect2, varscan2
- RELCH | c.2739A>T p.G913= | Silent (SNP) | VAF 203/270 reads (75%) | catalogued as COSV99902811; called by muse, mutect2, varscan2
- RIPK4 | c.2454C>T p.G818= (on ENST00000352483; = p.G770= on NM_020639.3) | Silent (SNP) | VAF 53/95 reads (56%) | catalogued as rs767725466, COSV100205401; called by muse, mutect2, varscan2
- RNF217 | c.1290C>T p.I430= (on ENST00000521654 / NM_001286398.2; = p.I138= on NM_152553.5) | Silent (SNP) | VAF 23/70 reads (33%) | catalogued as COSV99255358; called by muse, mutect2, varscan2
- RREB1 | c.1893C>T p.G631= | Silent (SNP) | VAF 36/62 reads (58%) | catalogued as COSV100619868; called by muse, mutect2, varscan2
- SLC16A10 | c.1437G>A p.E479= | Silent (SNP) | VAF 115/149 reads (77%) | catalogued as COSV64356272; called by muse, mutect2, varscan2
- SMPD2 | c.807C>T p.L269= | Silent (SNP) | VAF 68/91 reads (75%) | catalogued as COSV99238180; called by muse, mutect2, varscan2
- SMYD1 | c.903G>T p.V301= | Silent (SNP) | VAF 14/84 reads (17%) | catalogued as COSV101352524; called by muse, mutect2, varscan2
- SUN1 | c.693G>A p.A231= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as rs371413624, COSV100568816; called by muse, mutect2, varscan2
- TFAP4 | c.168C>T p.N56= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs1465706654, COSV99200039; called by muse, mutect2, varscan2
- TFDP3 | c.1206C>T p.D402= | Silent (SNP) | VAF 38/49 reads (78%) | catalogued as rs1166233911, COSV100033549; called by muse, mutect2, varscan2
- UBALD2 | c.141C>T p.F47= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as COSV100548329; called by muse, mutect2, varscan2
- ZADH2 | c.444C>T p.P148= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as rs370732101; called by muse, mutect2, varscan2
- ZNF536 | c.183C>T p.P61= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as rs761702298, COSV100835973, COSV62825501; called by muse, mutect2, varscan2
- IGLL5 | chr22:22901020 T>G | 3'Flank (SNP) | VAF 66/211 reads (31%) | called by muse, mutect2, varscan2
- IGLL5 | chr22:22901021 C>A | 3'Flank (SNP) | VAF 66/212 reads (31%) | called by muse, mutect2, varscan2
- MIR518F | n.32T>G | RNA (SNP) | VAF 55/121 reads (45%) | called by muse, mutect2, varscan2
